Somatic mutation profile of tumor specimen TCGA-17-Z021-01A (aliquot TCGA-17-Z021-01A-01W-0746-08) from TCGA case TCGA-17-Z021, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d74b882c-ee9e-4f4d-bbcb-a1cd3e92c63b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z021-11A (Solid Tissue Normal), aliquot TCGA-17-Z021-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46b86010-698f-4bdf-ad39-94668dadfffd

The open-access MAF lists 135 somatic variants for this specimen: 95 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 37, Nonsense Mutation 11, Splice Site 3, RNA 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376-2A>T p.X126_splice | Splice Site (SNP) | VAF 3/56 reads (5%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic / not provided; called by muse, mutect2
- ABCB11 | c.677C>A p.S226* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | catalogued as CM103531, COSV55591915; called by muse, mutect2
- ABCB4 | c.3388G>A p.D1130N (on ENST00000265723 / NM_018849.3; = p.D1123N on NM_000443.4) | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.85); catalogued as rs866301089; called by muse, mutect2
- BACH2 | c.1461del p.D488Tfs*79 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | catalogued as COSV57585977; called by mutect2, pindel, varscan2
- CNGB3 | c.733C>A p.Q245K | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60688044, COSV60700356; called by muse, mutect2, varscan2
- CNTNAP2 | c.2043C>A p.Y681* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV62163745; called by muse, mutect2, varscan2
- COL19A1 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.842); catalogued as rs1273728514; called by muse, mutect2, varscan2
- CRMP1 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 10/97 reads (10%) | catalogued as COSV61479154; called by muse, varscan2
- CXorf66 | c.743C>A p.S248* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV100983927; called by muse, mutect2
- DHX35 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52667114; called by muse, mutect2, varscan2
- DNAH8 | c.8408T>C p.I2803T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.201); catalogued as rs1326318481; called by muse, mutect2, varscan2
- F8 | c.4233G>T p.K1411N | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV64273695; called by muse, mutect2
- FCAR | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV62028137, COSV62032319; called by muse, mutect2, varscan2
- GHR | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.187); catalogued as COSV50110658; called by muse, mutect2
- HELZ | c.123G>T p.M41I | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1267908280; called by muse, mutect2
- KIF26B | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63643371; called by muse, mutect2
- LEPR | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs761476449; called by mutect2, varscan2
- LPP | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.1); catalogued as rs756633064; called by muse, mutect2, varscan2
- LRP1B | c.3413C>A p.P1138Q | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV67201818; called by muse, mutect2
- LRRC66 | c.1575G>C p.Q525H | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.737); catalogued as COSV58634093; called by muse, mutect2
- NUP188 | c.2570A>G p.K857R | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs1324225588; called by muse, mutect2, varscan2
- OR2M3 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV101513447; called by muse, mutect2
- PCK1 | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1306089208, COSV100100854; called by muse, mutect2
- PTPRD | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61973893; called by muse, mutect2, varscan2
- SETD2 | c.6362G>T p.R2121L | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57441748; called by muse, mutect2
- SMC3 | c.2950A>C p.K984Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752190321; called by muse, mutect2, varscan2
- TANC2 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 14/131 reads (11%) | catalogued as COSV67336078; called by muse, mutect2, varscan2
- TEP1 | c.7561C>G p.P2521A | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV99403014; called by muse, mutect2, varscan2
- THAP2 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs1157514508; called by mutect2, varscan2
- THSD7B | c.2150G>T p.R717I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV55697741; called by muse, mutect2, varscan2
- A1CF | c.587G>T p.R196M | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- ABCA8 | c.3751G>T p.G1251W | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACAP2 | c.487A>T p.R163* | Nonsense Mutation (SNP) | VAF 7/75 reads (9%) | called by muse, varscan2
- ACKR1 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ACSM2A | c.707C>A p.S236* (on ENST00000219054; = p.S157* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 15/160 reads (9%) | called by muse, mutect2, varscan2
- ADAM12 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2
- ADGRG2 | c.542C>G p.A181G (on ENST00000379869 / NM_001079858.3; = p.A178G on NM_005756.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.103); called by muse, varscan2
- ADGRL4 | c.615T>A p.D205E | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.309); called by muse, mutect2
- AHNAK2 | c.9496G>T p.V3166L | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2
- AMER1 | c.1866G>T p.E622D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ANK2 | c.9227A>T p.Q3076L | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ANK3 | c.12475A>G p.T4159A (on ENST00000280772 / NM_001320874.2; = p.T680A on NM_001149.3) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CDH23 | c.8846A>G p.Y2949C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- CFAP47 | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CLTC | c.3354A>T p.K1118N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- CMTR2 | c.950G>A p.C317Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNOT1 | c.5185G>C p.E1729Q | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.222); called by muse, mutect2
- DAB1 | c.1544-2A>T p.X515_splice (on ENST00000371231; = p.X482_splice on NM_021080.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- ERBB4 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXJ1 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRP | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.021); called by mutect2, varscan2
- GOT1L1 | c.672G>T p.L224F | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- HRNR | c.848A>G p.Y283C | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- IGKV2D-29 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2
- ITGAM | c.1546C>A p.Q516K (on ENST00000648685 / NM_001145808.2; = p.Q515K on NM_000632.4) | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- JARID2 | c.791A>T p.Q264L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNQ5 | c.2100G>T p.Q700H | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- KRT36 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- KRTAP11-1 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2
- LEPR | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2
- LRRC66 | c.1576G>T p.D526Y | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2
- LYST | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.193); called by muse, mutect2
- MAGEB4 | c.982A>G p.T328A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.019); called by muse, mutect2
- MRC1 | c.1951G>T p.G651C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); called by muse, mutect2
- MTOR | c.7049G>T p.S2350I | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- MUC16 | c.6472G>A p.G2158S | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- MYH10 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- NKAIN2 | c.429C>A p.Y143* | Nonsense Mutation (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- NOTCH4 | c.1724G>T p.C575F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUDT11 | c.211G>T p.G71* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- OIT3 | c.309G>T p.Q103H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- OSBPL6 | c.2026C>A p.P676T | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTULINL | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PCSK5 | c.4252T>A p.C1418S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2
- PGK1 | c.756+1G>T p.X252_splice | Splice Site (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- POT1 | c.221A>T p.K74I | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRKDC | c.12130A>C p.I4044L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2
- PRRT2 | c.529del p.E177Kfs*52 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | called by mutect2, pindel, varscan2
- RAB33A | c.226A>C p.K76Q | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2
- RAB38 | c.410T>A p.M137K | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- RAP2C | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2
- RIOK1 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- SEPTIN4 | c.64A>C p.T22P | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.653); called by muse, mutect2
- SLC11A1 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SLC15A1 | c.2111C>G p.S704* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | called by mutect2, varscan2
- SLC7A4 | c.1018C>A p.L340M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- SRP72 | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.045); called by muse, mutect2
- STARD13 | c.2300G>C p.R767P (on ENST00000336934 / NM_001243476.3; = p.R649P on NM_052851.3) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- TAS2R42 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2
- TFAP2D | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- TMEM132E | c.1061T>A p.L354Q (on ENST00000321639; = p.L444Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- TRIM15 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- TRPS1 | c.88G>C p.V30L (on ENST00000220888 / NM_001330599.2; = p.V43L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by mutect2, varscan2
- ZNF682 | c.1207G>T p.G403C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF85 | c.1479G>T p.W493C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADAMTS20 | c.144C>A p.V48= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs781460004, COSV67140932; called by mutect2, varscan2
- ANK2 | c.11634C>A p.P3878= | Silent (SNP) | VAF 18/245 reads (7%) | called by muse, mutect2
- AOC2 | c.501G>T p.V167= | Silent (SNP) | VAF 7/39 reads (18%) | called by mutect2, varscan2
- BTN3A2 | c.654A>T p.V218= | Silent (SNP) | VAF 12/161 reads (7%) | called by muse, mutect2
- C16orf70 | c.477T>C p.S159= | Silent (SNP) | VAF 6/71 reads (8%) | called by muse, mutect2
- C19orf57 | c.1740T>A p.V580= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- CARMIL3 | c.4047C>T p.S1349= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1293855772; called by muse, mutect2
- CNTN5 | c.732G>T p.R244= | Silent (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2
- CRB1 | c.3120C>A p.S1040= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- CRYGS | c.351C>T p.S117= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV57193059; called by muse, mutect2, varscan2
- DCK | c.183T>A p.V61= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- DPP4 | c.543A>T p.P181= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- ERAP2 | c.1998G>T p.V666= | Silent (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2
- FLG | c.5392C>A p.R1798= | Silent (SNP) | VAF 30/275 reads (11%) | catalogued as rs149105551; called by muse, varscan2
- GKN1 | c.45A>T p.L15= | Silent (SNP) | VAF 14/102 reads (14%) | called by muse, varscan2
- GLRB | c.207C>T p.P69= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- GRID2 | c.2496A>T p.A832= | Silent (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- HEPH | c.2463C>A p.I821= (on ENST00000343002; = p.I554= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1309878655; called by muse, mutect2
- KIF21B | c.2043A>T p.T681= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- LMX1A | c.603C>A p.I201= | Silent (SNP) | VAF 18/263 reads (7%) | called by muse, mutect2
- LRFN2 | c.1611C>T p.V537= | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2
- LRP2 | c.7005C>A p.P2335= | Silent (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- MED7 | c.381A>T p.R127= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- MGAT3 | c.681G>A p.E227= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV57868696; called by muse, mutect2, varscan2
- MINAR1 | c.1506C>T p.H502= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- OR2AK2 | c.198C>A p.L66= | Silent (SNP) | VAF 17/266 reads (6%) | called by muse, mutect2
- OR7C1 | c.771G>T p.G257= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- PCK1 | c.1527C>A p.P509= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100100134; called by muse, mutect2
- PLEKHM3 | c.165A>T p.T55= | Silent (SNP) | VAF 7/185 reads (4%) | called by muse, mutect2
- PPARGC1A | c.2214G>A p.L738= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- SI | c.2859A>G p.Q953= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs1444268809; ClinVar: uncertain significance; called by muse, mutect2
- SLC9C2 | c.2031T>C p.F677= | Silent (SNP) | VAF 10/77 reads (13%) | called by mutect2, varscan2
- TANC1 | c.916C>T p.L306= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- TTN | c.63612T>A p.P21204= (on ENST00000591111; = p.P13780= on NM_003319.4) | Silent (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- VWCE | c.2245C>T p.L749= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- ZFHX4 | c.381A>T p.L127= | Silent (SNP) | VAF 22/195 reads (11%) | called by muse, mutect2, varscan2
- ZNF536 | c.3117C>A p.V1039= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100836007; called by muse, mutect2, varscan2
- C2orf83 | n.477A>C | RNA (SNP) | VAF 9/85 reads (11%) | called by mutect2, varscan2
- IGKV1-13 | n.325T>C | RNA (SNP) | VAF 28/582 reads (5%) | called by muse, mutect2
- LINC02877 | n.283A>G | RNA (SNP) | VAF 14/350 reads (4%) | called by muse, mutect2
